Somatic mutation profile of tumor specimen MMRF_1730_1_BM_CD138pos (aliquot MMRF_1730_1_BM_CD138pos_T1_KBS5U_L04786) from MMRF case MMRF_1730, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.8 years (18,560 days).
Specimen MMRF_1730_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46198c42-6c49-40dc-8163-ddf578705b68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1730_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1730_1_PB_Whole_C3_KBS5U_L04799; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01434f05-b42b-4a86-a8c6-007c65797865

The open-access MAF lists 61 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 13, Silent 10, Intron 9, 5'UTR 2, Nonsense Mutation 2, 5'Flank 2, RNA 1, 3'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 67/129 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACKR2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757492481; called by muse, mutect2, varscan2
- DCDC1 | c.5224G>T p.E1742* (on ENST00000597505 / NM_001367979.1; = p.E849* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs764146895, COSV100360827; called by muse, mutect2, varscan2
- IGHJ5 | c.35T>A p.V12D | Missense Mutation (SNP) | VAF 26/30 reads (87%) | PolyPhen probably damaging (0.927); catalogued as rs368830933; called by muse, varscan2
- INSYN2A | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV54743255; called by muse, mutect2, varscan2
- MKRN3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs140349866; called by muse, mutect2, varscan2
- PCSK6 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs757508987; called by muse, mutect2, varscan2
- RYR1 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs1202647394, COSV62089209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPOAP1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs754322033; called by muse, mutect2, varscan2
- BICRA | c.3246C>A p.A1082= | Splice Region (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- CASP5 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2
- CDH23 | c.7339A>T p.K2447* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- GNAI1 | c.770A>T p.K257M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- INSYN2A | c.824C>G p.A275G | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRP1B | c.2816G>A p.C939Y | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MATR3 | c.627A>C p.Q209H | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NLRP13 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.149); called by muse, mutect2
- NRK | c.2054A>C p.K685T | Missense Mutation (SNP) | VAF 82/88 reads (93%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OR7C1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PTK6 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC26A9 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLC49A3 | c.1625G>A p.R542K (on ENST00000404286 / NM_001294341.2; = p.R541K on NM_032219.4) | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SON | c.283_297del p.V95_P99del | In Frame Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- BHMT2 | c.675T>C p.G225= | Silent (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- CACNA1E | c.3513G>A p.A1171= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as rs565145928, COSV62433924; called by muse, mutect2, varscan2
- CRTAC1 | c.1239C>T p.D413= | Silent (SNP) | VAF 12/171 reads (7%) | catalogued as rs558485684, COSV54010966; called by muse, mutect2
- GASK1B | c.501T>C p.A167= | Silent (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- GPR143 | c.702C>T p.N234= | Silent (SNP) | VAF 54/56 reads (96%) | catalogued as rs138339667; called by muse, mutect2, varscan2
- MFAP3L | c.987T>C p.H329= | Silent (SNP) | VAF 77/148 reads (52%) | called by muse, mutect2, varscan2
- NUP188 | c.4020C>T p.L1340= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1214282846; called by muse, mutect2, varscan2
- OR2B6 | c.519G>A p.V173= | Silent (SNP) | VAF 30/284 reads (11%) | catalogued as COSV55129094; called by muse, mutect2, varscan2
- PNLIPRP2 | c.435G>C p.A145= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV53942252; called by muse, mutect2, varscan2
- SIGLEC5 | c.987C>G p.L329= | Silent (SNP) | VAF 64/194 reads (33%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501958 del AA | 5'Flank (DEL) | VAF 51/144 reads (35%) | catalogued as rs771833705; called by mutect2, pindel, varscan2
- CAV3 | c.*741G>A | 3'UTR (SNP) | VAF 31/56 reads (55%) | catalogued as rs560215660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP19 | c.*1256A>C | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2
- DAPK3 | c.*69C>T | 3'UTR (SNP) | VAF 12/32 reads (38%) | catalogued as rs958800634; called by muse, mutect2
- DIP2C | c.85+37156G>A | Intron (SNP) | VAF 128/136 reads (94%) | called by muse, mutect2, varscan2
- ELMO2 | c.808-920C>T | Intron (SNP) | VAF 130/268 reads (49%) | called by muse, varscan2
- ENPP1 | c.*3305C>T | 3'UTR (SNP) | VAF 64/77 reads (83%) | called by muse, mutect2, varscan2
- FAM24B | chr10:122846103 del GA | 3'Flank (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- FBXO42 | c.*1281C>T | 3'UTR (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- FRMD5 | c.*1289T>C | 3'UTR (SNP) | VAF 33/106 reads (31%) | called by muse, mutect2, varscan2
- GATAD2B | c.*4518dup | 3'UTR (INS) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- GRM7 | c.2452-43632T>G | Intron (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- HERPUD1 | c.906-56_906-53del | Intron (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- IP6K1 | c.*2274T>A | 3'UTR (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100389809; called by muse, mutect2, varscan2
- LILRA5 | c.*153T>C | 3'UTR (SNP) | VAF 27/90 reads (30%) | catalogued as rs1207064901; called by muse, mutect2, varscan2
- LTB | c.163-109T>C | Intron (SNP) | VAF 172/323 reads (53%) | called by muse, varscan2
- MIER1 | c.180+955T>A | Intron (SNP) | VAF 49/102 reads (48%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851212 T>G | 5'Flank (SNP) | VAF 80/168 reads (48%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.*1415T>G | 3'UTR (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- PHEX | c.*3200T>C | 3'UTR (SNP) | VAF 35/37 reads (95%) | called by muse, mutect2, varscan2
- REL | c.-8G>C | 5'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- RPS15A | c.-5-9C>T | Intron (SNP) | VAF 187/423 reads (44%) | called by muse, mutect2, varscan2
- SCARA5 | c.1153+63C>A | Intron (SNP) | VAF 31/53 reads (58%) | catalogued as rs753362034; called by muse, mutect2, varscan2
- SDR16C6P | n.326G>A | RNA (SNP) | VAF 85/222 reads (38%) | called by muse, mutect2, varscan2
- SLC24A2 | c.-52A>G | 5'UTR (SNP) | VAF 95/258 reads (37%) | called by muse, mutect2, varscan2
- STK32A | c.*457G>T | 3'UTR (SNP) | VAF 134/509 reads (26%) | called by muse, mutect2, varscan2
- TTC9 | c.*2060G>A | 3'UTR (SNP) | VAF 45/94 reads (48%) | catalogued as rs904803963; called by muse, mutect2, varscan2
- ZNF425 | c.18+43G>A | Intron (SNP) | VAF 77/147 reads (52%) | called by muse, mutect2, varscan2
